Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MY-01A (Primary Tumor).

[page 1 of 2]
Specimen:
Procedure:
Accessioned:
Reported:
Submitting Phys:

Patient:
Medical Record #:
DOB/Age/Sex: (Age: F
Location/Client:

Surgical Pathology Report

**** Procedures/Addenda Added ****

Final Diagnosis

ADRENAL, RIGHT, ADRENALECTOMY:

- PHEOCHROMOCYTOMA (4 CM) WITH INFARCTION AND CYSTIC DEGENERATION.
- THERE IS NO IDENTIFIABLE CAPSULAR INVASION OR VASCULAR INVASION.
- THERE IS NO EVIDENCE OF TUMOR NECROSIS.
- MITOSES ARE EXTREMELY RARE.
- IMMUNOHISTOCHEMICAL STAIN FOR KI-67 SHOWS LOW LABELING OVERALL (APPROXIMATELY 1%) WITH SCATTERED SMALL HOT SPOTS.
- IMMUNOHISTOCHEMICAL STAIN FOR S-100 SHOWS SCATTERED SUSTENTACULAR CELLS.
- IMMUNOHISTOCHEMICAL STAIN FOR NEUROFILAMENT SHOWS FOCALLY PROMINENT NEURITES, SUGGESTING FOCAL NEURONAL DIFFERENTIATION.

***Report Electronically Signed By

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Addendum

Ordered:

Reported:

IHC is positive for SDHB protein, suggesting that mutation of SDHBx is not present.

Clinical History

Pheochromocytoma

Pre-Operative Diagnosis

{Not Provided}

Post-Operative Diagnosis

{Not Provided}

Gross Description

A. RIGHT ADRENAL (FRESH): The specimen, labeled with the patient's name and medical record number, is 5.6 x 4 x 2.5 cm lacerated adrenal gland with a small portion of adherent fat. The interior of the gland is replaced by a gray and purple, soft, friable hemorrhagic mass, approximately 4 x 4 x 2 cm in greatest dimension, with a 2 cm central cyst. The mass is partly encased by the smooth, gray capsule of the adrenal. However, because both the adrenal capsule and the mass are lacerated, capsule integrity cannot be completely assessed. There is no gross evidence of adrenal medullary hyperplasia. Approximately 70% of the tumor is sampled. A portion is submitted for tumor bank and possible future studies.

SECTION CODE

[page 2 of 2]
A1-2: TUMOR WITH CYST WALL (A2 – TWO FRAGMENTS).
A3: CYST WALL.
A4: ADJACENT ADRENAL.
A5: ADJACENT ADRENAL, GROSSLY UNINVOLVED (TWO FRAGMENTS).

Department of Pathology
- End of Report -

Page 2 of 2
Printed:

Source: NCI Genomic Data Commons file 0f906e49-1f82-4c44-998f-6268c0af5ff5 (TCGA-SR-A6MY.0835B9F9-524D-418C-B7AE-8593C50D12C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).